Gene-level copy-number profile of tumor specimen TCGA-BR-7197-01A from TCGA case TCGA-BR-7197, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 69.7 years (25,445 days).
Specimen TCGA-BR-7197-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3c3e0217-ef46-4168-be98-9223460236cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-7197-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e2949c68-8093-434c-acba-3d01f438d4da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 6,667; copy number 2: 29,114; copy number 3: 15,652; copy number 4: 3,123; copy number 5: 3,131; copy number 6: 1,965; copy number 8: 156; copy number 12: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-7197-01A-11D-2200-01): tumor purity 0.63, ploidy 2.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:113,376,669–113,377,227, 1 gene: AC107890.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,239 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,697,455–155,087,538, 20 genes, copy number 5 (within-gene range 3–5): KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3.
- chr1:225,401,502–225,653,142, 4 genes, copy number 5 (within-gene range 3–5): LBR, LINC02765, AC092811.1, ENAH.
- chr2:136,199,114–136,545,542, 5 genes, copy number 5: HNRNPKP2, AC112255.1, UBBP1, RN7SKP141, SMC4P1.
- chr2:218,781,749–219,185,475, 28 genes, copy number 6 (within-gene range 3–6): CYP27A1, AC009974.2, AC009974.1, PRKAG3, MIR9500, RPL23AP31, WNT6, WNT10A, LINC01494, RNU6-642P, AC097468.2, KRT8P30, CDK5R2, LINC00608, FEV, CRYBA2, MIR375, AC097468.1, CFAP65, IHH, MIR3131, AC097468.3, NHEJ1, AC068946.1, RN7SL764P, SLC23A3, CNPPD1, RETREG2.
- chr5:35,852,695–45,228,428, 164 genes, copy number 6–12 (broad region; genes not listed).
- chr5:74,766,991–75,236,911, 15 genes, copy number 5 (within-gene range 2–5): NSA2, FAM169A, RNU6-1330P, AC093214.1, AC010501.2, AC010501.1, AC116337.4, AC116337.3, AC116337.1, AC116337.2, RPL27AP5, AC093259.1, GCNT4, ANKRD31, SUMO2P5.
- chr7:70,972–87,480,435, 1,567 genes, copy number 5–6 (broad region; genes not listed).
- chr7:87,521,461–87,522,410, 1 gene, copy number 6: HNRNPA1P9.
- chr8:41,426,655–43,514,421, 70 genes, copy number 6 (broad region; genes not listed).
- chr8:100,257,060–101,669,726, 46 genes, copy number 5 (within-gene range 4–5): RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1.
- chr8:101,686,547–101,689,093, 1 gene, copy number 5: AP000426.1.
- chr8:133,644,598–145,066,685, 258 genes, copy number 5–6 (broad region; genes not listed).
- chr10:30,299,569–34,815,325, 81 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr10:120,925,547–121,185,966, 4 genes, copy number 6: AC010998.1, AC010998.3, RPL19P16, LINC01153.
- chr16:32,600,299–79,212,667, 981 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr16:78,355,529–90,222,851, 330 genes, copy number 5 (broad region; genes not listed).
- chr18:47,390–1,408,344, 43 genes, copy number 5: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr19:18,683,678–20,321,305, 84 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:28,435,388–32,719,595, 81 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:87,250–16,053,197, 293 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,238. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
